Somatic mutation profile of tumor specimen 0DN1DH from CCDI case PBCBDJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.7 years (5,723 days).
Specimen 0DN1DH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) acce6687-7e40-4654-a129-f7b7419fe5a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DN1BA (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/337c5c08-5b36-4857-9ba1-9476117f5e1b

The open-access MAF lists 34 somatic variants for this specimen: 22 protein-altering or splice-affecting, 7 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 7, Intron 4, Splice Site 1, 5'UTR 1, Splice Region 1, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRV1 | c.14774G>T p.G4925V | Missense Mutation (SNP) | VAF 247/559 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as rs895079652; called by muse, mutect2, varscan2
- ANPEP | c.2132G>A p.R711H | Missense Mutation (SNP) | VAF 153/614 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.513); catalogued as rs182672249; called by muse, mutect2, varscan2
- DEUP1 | c.1222dup p.M408Nfs*13 | Frame Shift Ins (INS) | VAF 75/425 reads (18%) | catalogued as rs755228434; called by mutect2, pindel, varscan2
- FAM155A | c.725A>G p.N242S | Missense Mutation (SNP) | VAF 242/516 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs537414485; called by muse, mutect2, varscan2
- FAM222B | c.833C>T p.T278M | Missense Mutation (SNP) | VAF 108/815 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); catalogued as rs575911818, COSV104418319; called by muse, varscan2
- FRG1 | c.741G>A p.R247= | Splice Region (SNP) | VAF 68/321 reads (21%) | catalogued as rs369974379; called by muse, mutect2, varscan2
- LCE6A | c.58C>T p.P20S | Missense Mutation (SNP) | VAF 266/664 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.457); catalogued as COSV70391107; called by muse, mutect2, varscan2
- SLC16A3 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 405/1314 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs868233860, COSV101125929; called by muse, mutect2, varscan2
- UGT1A5 | c.472G>A p.A158T | Missense Mutation (SNP) | VAF 50/744 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as rs762349371, COSV59392098; called by muse, mutect2
- CSMD3 | c.10118G>A p.S3373N (on ENST00000297405 / NM_001363185.1; = p.S3204N on NM_052900.3) | Missense Mutation (SNP) | VAF 122/289 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- GEMIN5 | c.1306C>A p.P436T | Missense Mutation (SNP) | VAF 149/790 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GNA13 | c.677A>T p.Q226L | Missense Mutation (SNP) | VAF 171/863 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.484); called by muse, mutect2, varscan2
- IARS2 | c.1066+1G>T p.X356_splice | Splice Site (SNP) | VAF 182/441 reads (41%) | called by muse, mutect2, varscan2
- IQCG | c.1069G>A p.A357T | Missense Mutation (SNP) | VAF 118/706 reads (17%) | SIFT tolerated (0.64); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- KMT2C | c.749G>A p.W250* | Nonsense Mutation (SNP) | VAF 241/536 reads (45%) | called by muse, mutect2, varscan2
- MAS1L | c.628C>T p.L210F | Missense Mutation (SNP) | VAF 196/489 reads (40%) | SIFT tolerated (0.69); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- NAV2 | c.2222A>G p.D741G (on ENST00000396087 / NM_001244963.2; = p.D718G on NM_145117.5) | Missense Mutation (SNP) | VAF 241/583 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PABPC4L | c.251T>C p.M84T | Missense Mutation (SNP) | VAF 111/614 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- POTEA | c.1310A>T p.N437I (on ENST00000519951 / NM_001005365.2; = p.N391I on NM_001002920.1) | Missense Mutation (SNP) | VAF 20/574 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.901); called by muse, mutect2
- PRDM7 | c.964G>A p.A322T | Missense Mutation (SNP) | VAF 227/586 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- RALGAPA1 | c.170T>C p.V57A | Missense Mutation (SNP) | VAF 57/320 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- SRXN1 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 70/347 reads (20%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- ALCAM | c.27C>T p.C9= | Silent (SNP) | VAF 139/649 reads (21%) | called by muse, mutect2, varscan2
- DUSP11 | c.750T>C p.P250= | Silent (SNP) | VAF 288/714 reads (40%) | called by muse, mutect2, varscan2
- MAGEA1 | c.495C>A p.T165= | Silent (SNP) | VAF 100/252 reads (40%) | catalogued as COSV63118463; called by muse, mutect2, varscan2
- OR10H3 | c.249G>C p.L83= | Silent (SNP) | VAF 26/818 reads (3%) | called by muse, mutect2
- RXRB | c.846A>G p.G282= | Silent (SNP) | VAF 56/290 reads (19%) | called by muse, mutect2, varscan2
- SEC24B | c.2949A>G p.L983= | Silent (SNP) | VAF 132/351 reads (38%) | catalogued as COSV99493106; called by muse, mutect2, varscan2
- SSUH2 | c.1023C>T p.D341= | Silent (SNP) | VAF 30/996 reads (3%) | called by muse, mutect2
- C1orf35 | c.534-52C>G | Intron (SNP) | VAF 96/176 reads (55%) | called by muse, mutect2, varscan2
- DDX60L | c.4929-40G>A | Intron (SNP) | VAF 23/135 reads (17%) | called by muse, mutect2, varscan2
- MEMO1 | c.-84C>G | 5'UTR (SNP) | VAF 24/76 reads (32%) | catalogued as rs1467264946; called by muse, varscan2
- SLC45A1 | c.716-54G>A | Intron (SNP) | VAF 77/340 reads (23%) | catalogued as rs1324488849; called by muse, mutect2, varscan2
- UNC119 | c.610+19C>T | Intron (SNP) | VAF 276/1088 reads (25%) | called by muse, mutect2, varscan2
